Somatic mutation profile of tumor specimen TCGA-W4-A7U4-01A (aliquot TCGA-W4-A7U4-01A-12D-A435-10) from TCGA case TCGA-W4-A7U4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 23.3 years (8,518 days).
Specimen TCGA-W4-A7U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aacbd9fe-91e8-4cb8-8ec0-8fa678b3acc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W4-A7U4-10A (Blood Derived Normal), aliquot TCGA-W4-A7U4-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3da5746-03af-48cc-bf9f-e5ee88b055fd

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, RNA 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATCAY | c.665del p.L222* | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as COSV56655088; called by mutect2, pindel, varscan2
- ITPR3 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65412594; called by muse, mutect2
- B3GNT8 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- BROX | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- ELMO2 | c.321G>A p.L107= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as rs375853555; called by muse, mutect2, varscan2
